Somatic mutation profile of tumor specimen TCGA-Q3-AA2A-01A (aliquot TCGA-Q3-AA2A-01A-11D-A377-08) from TCGA case TCGA-Q3-AA2A, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IB; Tumor grade: G1; Age at diagnosis: 64.8 years (23,685 days).
Specimen TCGA-Q3-AA2A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32015997-f99c-44ba-b964-c606c84c5bfa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Q3-AA2A-10A (Blood Derived Normal), aliquot TCGA-Q3-AA2A-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14d328dd-a007-4b2c-b97b-70c00c8c6acc

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 16, Silent 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 122/396 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRIT1 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 105/348 reads (30%) | catalogued as rs866982998, CM1413284; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AMER2 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs769578072, COSV63436480; called by muse, mutect2, varscan2
- BTBD11 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 46/259 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99775728; called by muse, mutect2, varscan2
- CLTCL1 | c.2639C>A p.A880D | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555952375, COSV99595038; called by muse, mutect2, varscan2
- CNTN3 | c.2431G>A p.A811T | Missense Mutation (SNP) | VAF 96/364 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as rs756391551, COSV55181727, COSV99724420; called by muse, mutect2, varscan2
- DNAH2 | c.9265G>C p.E3089Q | Missense Mutation (SNP) | VAF 101/410 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.292); catalogued as COSV101209300; called by muse, varscan2
- ELOVL4 | c.215C>A p.P72H | Missense Mutation (SNP) | VAF 83/381 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778982572, COSV100876267; called by muse, mutect2, varscan2
- GABRR3 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs772326338, COSV101512284, COSV72084027; called by muse, mutect2, varscan2
- ITGB1BP1 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 95/311 reads (31%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.506); catalogued as rs17850889; called by muse, mutect2, varscan2
- MTUS2 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs779266664, COSV70914997; called by muse, mutect2, varscan2
- OSMR | c.319T>C p.C107R | Missense Mutation (SNP) | VAF 109/465 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99953141; called by muse, mutect2, varscan2
- PCDHGA10 | c.1913A>G p.D638G | Missense Mutation (SNP) | VAF 58/490 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV99538177; called by muse, mutect2, varscan2
- PLAAT5 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 444/1527 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as COSV100080482; called by muse, mutect2, varscan2
- UROC1 | c.1291C>A p.P431T | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1407097136, COSV99331451; called by muse, mutect2, varscan2
- ZFP69 | c.76G>A p.V26M | Missense Mutation (SNP) | VAF 9/276 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1197632620, COSV65528328; called by muse, mutect2
- ITFG2 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MOSPD3 | c.429G>A p.E143= | Silent (SNP) | VAF 22/335 reads (7%) | catalogued as COSV99774940; called by muse, mutect2
- PRPF38A | c.42C>G p.G14= | Silent (SNP) | VAF 48/399 reads (12%) | catalogued as COSV99933303; called by muse, mutect2, varscan2
- PTPRF | c.2220G>A p.Q740= | Silent (SNP) | VAF 40/283 reads (14%) | catalogued as COSV100740896; called by muse, mutect2, varscan2
- TFDP1 | c.72C>T p.P24= | Silent (SNP) | VAF 119/507 reads (23%) | catalogued as rs144432965; called by muse, mutect2, varscan2
- TTI1 | c.1548G>A p.V516= | Silent (SNP) | VAF 66/275 reads (24%) | catalogued as COSV100989639, COSV65061636; called by muse, mutect2, varscan2
- ZFAND2A | c.216A>T p.P72= | Silent (SNP) | VAF 151/695 reads (22%) | catalogued as rs1200345406, COSV100335896; called by muse, mutect2, varscan2
